Somatic mutation profile of tumor specimen SM-JU34E (aliquot 7316UP-485) from CPTAC case C243909, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU34E: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54390ae5-6e08-49a4-a8f3-9ae8427a8d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105279 (Blood Derived Normal), aliquot 7316UP-219-1105279; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/012ccdf0-d9b0-44da-b800-e1162448be2f

The open-access MAF lists 784 somatic variants for this specimen: 523 protein-altering or splice-affecting, 170 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 434, Silent 170, Nonsense Mutation 43, Intron 41, RNA 18, Frame Shift Del 17, 3'UTR 12, Splice Site 11, 5'UTR 11, Splice Region 8, 3'Flank 5, Frame Shift Ins 5.

Variants (750 of 784; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2
- TMEM67 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs762543032, CM100393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 108/164 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 42/163 reads (26%) | catalogued as COSV50958623; called by muse, mutect2, varscan2
- ADAMTS2 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 37/205 reads (18%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- ANO7 | c.962C>A p.A321E (on ENST00000274979; = p.A267E on NM_001370694.2) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375507696; called by muse, mutect2, varscan2
- ANXA13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1409407846; called by muse, mutect2, varscan2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- ARAP3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1186879516; called by muse, mutect2, varscan2
- ARFGAP3 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV54311444; called by muse, mutect2, varscan2
- ARHGAP12 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60961844, COSV60963784; called by muse, mutect2, varscan2
- ARHGAP22 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201381170; called by muse, mutect2, varscan2
- ASTN1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56072577; called by muse, mutect2, varscan2
- ATP13A4 | c.3488G>C p.S1163T | Missense Mutation (SNP) | VAF 37/444 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV61315960; called by muse, mutect2
- ATP6V0A2 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs199578524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.2995A>T p.R999* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as CD084049; called by muse, mutect2
- BRWD3 | c.3224C>A p.P1075Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1051653380; called by muse, mutect2
- C20orf144 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 152/371 reads (41%) | catalogued as rs1183825290; called by muse, mutect2, varscan2
- C9orf131 | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1380081534; called by muse, mutect2, varscan2
- CACNA1E | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs769941881, COSV62394979, COSV62397581; called by muse, mutect2
- CACNA1G | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs766099998; called by muse, mutect2, varscan2
- CACNA2D2 | c.2869C>T p.R957W (on ENST00000479441 / NM_001174051.3; = p.R950W on NM_006030.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209696501, COSV99817832; ClinVar: uncertain significance; called by muse, mutect2
- CAPN15 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836374, COSV99562579; called by muse, mutect2, varscan2
- CDC40 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs890438403; called by muse, mutect2, varscan2
- CDH9 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV50300303; called by muse, mutect2
- CDK1 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358872; called by muse, mutect2
- CDX4 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV100999147; called by muse, mutect2, varscan2
- CEP85 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs150424067; called by muse, mutect2, varscan2
- COL22A1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57364241; called by muse, mutect2, varscan2
- CPLANE1 | c.7838C>G p.S2613* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV99949726; called by muse, mutect2
- CRACD | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs776352029; called by muse, mutect2, varscan2
- CSMD1 | c.9653C>A p.P3218Q (on ENST00000520002; = p.P3217Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV59306150; called by muse, mutect2
- CSMD1 | c.3701G>T p.G1234V (on ENST00000520002; = p.G1233V on NM_033225.6) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs763737608; called by muse, mutect2, varscan2
- CSMD3 | c.9299G>T p.G3100V (on ENST00000297405 / NM_001363185.1; = p.G2931V on NM_052900.3) | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, mutect2, varscan2
- CSMD3 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 182/301 reads (60%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as COSV52092277, COSV52126694; called by muse, mutect2, varscan2
- DAAM1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62834150; called by muse, mutect2, varscan2
- DAGLB | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs755797799; called by muse, mutect2, varscan2
- DCDC1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs566810543; called by muse, mutect2, varscan2
- DES | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64660959; called by muse, mutect2, varscan2
- DGKQ | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as COSV99298305; called by muse, mutect2, varscan2
- DMD | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1477425663; called by muse, mutect2, varscan2
- DNAH5 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs773648190; called by muse, mutect2
- DST | c.2437G>A p.D813N (on ENST00000361203 / NM_001374722.1; = p.D487N on NM_001723.6) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs367639314; called by muse, mutect2, varscan2
- DUSP10 | c.989T>A p.F330Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1198360310; called by muse, mutect2
- DYNC1I1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100268810, COSV61468022; called by muse, mutect2, varscan2
- EOMES | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs536220570; called by muse, mutect2, varscan2
- EPHA4 | c.2197G>T p.G733W | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037210; called by muse, mutect2, varscan2
- ERGIC2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774859065; called by muse, mutect2, varscan2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- EYS | c.3684G>A p.M1228I | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58203363; called by muse, mutect2, varscan2
- F7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs147680958, CM001151; called by muse, mutect2, varscan2
- FAM184B | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as rs1188972903, COSV53957258; called by muse, mutect2, varscan2
- FARP2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs777762724; called by muse, mutect2
- FGA | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs746087673, CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FKBP1B | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1431748983, COSV99272892, COSV99273018; called by muse, mutect2, varscan2
- FLII | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58943841; called by muse, mutect2, varscan2
- FSIP2 | c.15454G>A p.E5152K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1197100532; called by muse, mutect2, varscan2
- FUT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs768236330, COSV67179035; called by muse, mutect2, varscan2
- GABPA | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61396593; called by muse, mutect2
- GABRA5 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV59479388; called by muse, varscan2
- GGPS1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51396852; called by muse, mutect2
- GPM6A | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1345183983; called by muse, mutect2
- GPRASP1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as rs1294027624, COSV100851087; called by muse, mutect2, varscan2
- GRM8 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100283592; called by muse, mutect2, varscan2
- HCST | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs777647806; called by muse, mutect2, varscan2
- HDAC9 | c.2035C>A p.R679= | Splice Region (SNP) | VAF 66/104 reads (63%) | catalogued as COSV67786067; called by muse, mutect2, varscan2
- HERC2 | c.7361C>T p.S2454L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs879255382, COSV55350151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPH2 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.899); catalogued as COSV57266118; called by muse, mutect2
- HOXC8 | c.312A>T p.Q104H | Missense Mutation (SNP) | VAF 61/559 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV50000548; called by muse, mutect2, varscan2
- HS3ST6 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs567994936; called by muse, mutect2, varscan2
- HUS1B | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs1166501299, COSV100032947, COSV57870288; called by muse, mutect2
- IGSF9B | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100317579; called by muse, mutect2, varscan2
- IL11RA | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 84/252 reads (33%) | catalogued as rs775348905; called by muse, mutect2, varscan2
- IL27RA | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs994827825, COSV54599596; called by muse, mutect2, varscan2
- INSYN2B | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99911494; called by muse, mutect2, varscan2
- IPP | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs780057516; called by muse, mutect2
- IQSEC2 | c.877G>T p.A293S (on ENST00000642864 / NM_001111125.3; = p.A88S on NM_015075.2) | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV64728202; called by muse, mutect2
- ITGBL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66009702; called by muse, mutect2, varscan2
- IVL | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 25/219 reads (11%) | catalogued as COSV64217090; called by muse, mutect2, varscan2
- JMJD1C | c.6317C>T p.P2106L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59512542; called by muse, varscan2
- KALRN | c.3252C>A p.N1084K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53785502; called by muse, mutect2, varscan2
- KCNQ3 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.548); catalogued as rs1172699877; called by muse, mutect2
- KEAP1 | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV50262958; called by muse, mutect2, varscan2
- KLHL29 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771088004; called by muse, mutect2, varscan2
- KLRC2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs1401787503, COSV67900231; called by muse, mutect2
- KRT84 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 268/454 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1475558984; called by muse, mutect2, varscan2
- LAMA5 | c.4299C>G p.N1433K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs576766054, COSV99439506; called by muse, mutect2, varscan2
- LRCH1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1209521446, COSV60844120; called by muse, mutect2, varscan2
- LRRC7 | c.3160C>A p.P1054T (on ENST00000651989 / NM_001370785.2; = p.P1021T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1428457255, COSV50608408; called by muse, varscan2
- LRRFIP1 | c.1147G>A p.E383K (on ENST00000392000 / NM_001137552.2; = p.E359K on NM_004735.4) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs147303790; called by muse, mutect2
- MALRD1 | c.6098G>T p.G2033V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1423736208; called by muse, mutect2, varscan2
- MARCKS | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 167/312 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100893018; called by muse, mutect2, varscan2
- MAT2B | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV55201041; called by muse, mutect2, varscan2
- MC3R | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV54763127; called by muse, mutect2
- MGAT2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1476271337, COSV53567037; called by muse, mutect2, varscan2
- MIPOL1 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59390976; called by muse, mutect2, varscan2
- MMP2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161173; called by muse, mutect2, varscan2
- MPP7 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.55); catalogued as rs762252605, COSV61739431; called by muse, mutect2, varscan2
- MUC17 | c.9346C>A p.P3116T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs562321094; called by muse, mutect2, varscan2
- MUC22 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious, low confidence (0.01); catalogued as rs1225649659, COSV73736210; called by muse, mutect2, varscan2
- MYO10 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.034); catalogued as COSV99946185; called by muse, mutect2
- N6AMT1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs757481872; called by muse, mutect2
- NBPF10 | c.1976C>G p.A659G | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.333); catalogued as rs782224083; called by muse, mutect2
- NEFL | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563251398, COSV99648163; ClinVar: uncertain significance; called by muse, mutect2
- NLRP1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 246/422 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs145709003; called by mutect2, varscan2
- NLRP5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs372305298, COSV66768008; called by muse, mutect2, varscan2
- NOP58 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51895561; called by muse, mutect2, varscan2
- NPBWR2 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.14); catalogued as COSV63900403; called by muse, mutect2, varscan2
- NPY1R | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV56714298, COSV56715481; called by muse, mutect2, varscan2
- NRBP1 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 134/293 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51993925; called by muse, mutect2, varscan2
- NTRK1 | c.354T>A p.S118R | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as CD087748; called by muse, mutect2, varscan2
- OLFML2A | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202197796; called by muse, mutect2, varscan2
- OR14A16 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1374004830; called by muse, mutect2, varscan2
- OR2T33 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58815134; called by muse, mutect2, varscan2
- OR4A16 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV59045243, COSV59045505; called by muse, mutect2
- OR51B2 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs758948105; called by muse, mutect2, varscan2
- P3H1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs200935208; called by muse, mutect2, varscan2
- PASD1 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.224); catalogued as rs773014348; called by muse, mutect2, varscan2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 116/301 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2, varscan2
- PCDHGB1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs551145874, COSV53913385; called by muse, mutect2, varscan2
- PCDHGB5 | c.2397+4A>T | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as rs764084750; called by muse, varscan2
- PCNX2 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237031185, COSV99265907; called by muse, mutect2, varscan2
- PGAP6 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739093; called by muse, mutect2, varscan2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, mutect2, varscan2
- PIN4 | c.353C>A p.P118Q (on ENST00000664196; = p.P93Q on NM_006223.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1423088655, COSV54485019; called by muse, mutect2, varscan2
- PLCE1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs754933489, COSV53357882; called by muse, mutect2, varscan2
- POTEA | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs527259841; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRDM10 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV58802665; called by muse, mutect2, varscan2
- PSG9 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 109/171 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs749016381; called by muse, mutect2, varscan2
- PSMD3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs555631976; called by muse, mutect2, varscan2
- PTPRD | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV61926583, COSV61978921; called by muse, mutect2
- PXDNL | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs754362945; called by muse, mutect2, varscan2
- PXDNL | c.886A>T p.R296* | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | catalogued as COSV62487640; called by muse, mutect2, varscan2
- RAB3IL1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as rs749370411; called by muse, mutect2, varscan2
- RASA2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770448162; called by muse, mutect2, varscan2
- RBMXL2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs755396057; called by muse, mutect2, varscan2
- RNF115 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs782790501; called by muse, mutect2, varscan2
- RPTN | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60169158; called by muse, mutect2, varscan2
- RRM1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as rs779004662; called by muse, mutect2, varscan2
- RTN1 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV50718699, COSV50719661; called by muse, mutect2, varscan2
- RYR2 | c.9460G>T p.A3154S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63677166; called by muse, mutect2, varscan2
- RYR3 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV66776059; called by muse, mutect2, varscan2
- SCARA5 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs765093547; called by muse, mutect2, varscan2
- SCN5A | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.055); catalogued as COSV61133873; called by muse, mutect2, varscan2
- SEMA4A | c.1587del p.N530Tfs*2 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs1558163897; called by mutect2, pindel, varscan2
- SF3A1 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305781; called by muse, mutect2, varscan2
- SKOR1 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943427929, COSV58250085; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>A p.R911S | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093013; called by muse, mutect2, varscan2
- SLC5A11 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 145/231 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932697713, COSV61741032; called by muse, mutect2, varscan2
- SLC7A13 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV52532273; called by muse, mutect2, varscan2
- SLCO1A2 | c.1610G>T p.R537M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56598395; called by muse, mutect2
- SNTG1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99387058; called by muse, mutect2, varscan2
- SP3 | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022002; called by muse, mutect2, varscan2
- SPATA31A6 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 62/415 reads (15%) | catalogued as COSV60534229; called by muse, mutect2, varscan2
- SPTA1 | c.3189-1G>A p.X1063_splice | Splice Site (SNP) | VAF 19/160 reads (12%) | catalogued as COSV63760610; called by muse, mutect2, varscan2
- SRCAP | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52679522; called by muse, mutect2, varscan2
- SRCAP | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1386993634; called by muse, mutect2
- STAB1 | c.7091C>A p.T2364K | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100195323; called by muse, mutect2, varscan2
- STXBP5L | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56510181, COSV56514530; called by muse, mutect2, varscan2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/168 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2, varscan2
- SULF1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201774043, COSV52690552; called by muse, mutect2, varscan2
- SVEP1 | c.1876del p.A626Qfs*25 | Frame Shift Del (DEL) | VAF 43/98 reads (44%) | catalogued as COSV57049750; called by mutect2, pindel, varscan2
- SYNE1 | c.16868G>A p.R5623H (on ENST00000367255 / NM_182961.4; = p.R5552H on NM_033071.3) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs753544584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAP1 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs765958228; ClinVar: uncertain significance; called by muse, mutect2
- TENT5D | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV57638237; called by muse, mutect2, varscan2
- TG | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 146/372 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV55071873; called by muse, mutect2, varscan2
- TLL2 | c.2630A>G p.Q877R | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1287812731; called by muse, mutect2, varscan2
- TMEFF2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV55840180; called by muse, mutect2, varscan2
- TMEM200A | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1331253259; called by muse, mutect2, varscan2
- TMEM260 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839844; called by muse, mutect2
- TNN | c.412C>T p.L138= | Splice Region (SNP) | VAF 16/112 reads (14%) | catalogued as COSV53420870; called by muse, mutect2, varscan2
- TRAJ53 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | PolyPhen probably damaging (0.944); catalogued as rs900687390; called by muse, mutect2, varscan2
- TRIM10 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV100939565; called by muse, mutect2, varscan2
- TRIM58 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1201819173; called by muse, mutect2, varscan2
- TRIM7 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs954710762; called by muse, mutect2
- TRPC5 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53285039; called by muse, mutect2, varscan2
- UBR2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV65749302; called by muse, mutect2, varscan2
- UNC13C | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV52891998; called by muse, mutect2, varscan2
- USH2A | c.13561C>G p.P4521A | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV56406267; called by muse, mutect2, varscan2
- USH2A | c.9226G>T p.D3076Y | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56401181, COSV56439100; called by muse, mutect2, varscan2
- USP6 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 130/253 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs750862063; called by muse, mutect2, varscan2
- VAT1L | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758626119, COSV56817365; called by muse, mutect2, varscan2
- VAV3 | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58377874; called by muse, mutect2, varscan2
- VMP1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs368929171; called by muse, mutect2, varscan2
- VPS13B | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1169113054; called by muse, mutect2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2
- WSCD2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753595241; called by mutect2, varscan2
- XIRP2 | c.7027C>T p.L2343F (on ENST00000628543; = p.L2518F on NM_152381.6) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV54699812; called by muse, mutect2, varscan2
- XIRP2 | c.8725G>T p.V2909L (on ENST00000628543; = p.V3084L on NM_152381.6) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV54728257, COSV99039766; called by muse, mutect2, varscan2
- ZEB2 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100355670; called by muse, mutect2, varscan2
- ZFHX3 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs760180670; called by muse, mutect2, varscan2
- ZFPM1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60324082; called by muse, mutect2, varscan2
- ZIC5 | c.1150T>C p.F384L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs913484014; called by muse, mutect2, varscan2
- ZNF232 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs745741402; called by muse, mutect2, varscan2
- ZNF423 | c.2211C>G p.F737L (on ENST00000563137 / NM_001379286.1; = p.F729L on NM_015069.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99283511; called by muse, mutect2, varscan2
- ZNF438 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs199999473, COSV59194055; called by muse, mutect2, varscan2
- ZNF514 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 67/113 reads (59%) | catalogued as COSV99727697; called by muse, mutect2, varscan2
- ZNF705A | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1424881100; called by muse, mutect2, varscan2
- ZNF717 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs76889571, COSV68858133; called by muse, mutect2, varscan2
- ZP4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs376995776; called by muse, mutect2, varscan2
- ZSCAN1 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 25/191 reads (13%) | catalogued as rs761346628, COSV56609383; called by muse, mutect2, varscan2
- ABCA10 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC9 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC245033.1 | c.1677C>T p.D559= | Splice Region (SNP) | VAF 56/389 reads (14%) | called by muse, mutect2, varscan2
- ACIN1 | c.956_969del p.M319Tfs*25 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | called by mutect2, pindel
- ACOX1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM23 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 103/163 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS1 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS1 | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRA3 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ADGRE1 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2
- AGXT2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 46/653 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ALPK3 | c.4452C>G p.I1484M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER1 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- AMY2B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANK1 | c.3575C>A p.T1192N | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- APOL3 | c.270A>C p.R90S (on ENST00000349314 / NM_145640.2; = p.R19S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARMC4 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARMT1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10B | c.2444T>A p.L815Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 142/451 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP6V1G3 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf88 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf66 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- C17orf99 | c.369C>A p.S123= | Splice Region (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2
- C6orf118 | c.937-1G>C p.X313_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- CACNA1D | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CACNA1F | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CADM2 | c.613G>C p.V205L (on ENST00000407528 / NM_001167674.2; = p.V207L on NM_153184.4) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CALD1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC168 | c.7754G>T p.G2585V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC171 | c.3031C>A p.L1011I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC89 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCL3 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCNB3 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH23 | c.8641G>T p.V2881F | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CDH5 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CDHR1 | c.1117del p.Q373Rfs*42 | Frame Shift Del (DEL) | VAF 40/250 reads (16%) | called by mutect2, pindel, varscan2
- CENPJ | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP47 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP47 | c.6914G>T p.R2305L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP94 | c.1164G>T p.L388F (on ENST00000320267 / NM_001352064.2; = p.L394F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CHD6 | c.3322G>T p.G1108C | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHD7 | c.3172T>A p.L1058M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CHD8 | c.1922C>T p.A641V (on ENST00000646647 / NM_001170629.2; = p.A362V on NM_020920.4) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CHL1 | c.2569G>A p.D857N (on ENST00000397491 / NM_001253387.1; = p.D873N on NM_006614.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by mutect2, varscan2
- CHRD | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CHST7 | c.1415G>T p.R472M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIBAR2 | c.775A>T p.S259C | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CLDN14 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- CLEC1A | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CLEC3A | c.488G>A p.W163* (on ENST00000651443; = p.W154* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 56/243 reads (23%) | called by muse, mutect2, varscan2
- CLMN | c.648G>T p.R216S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- CLSPN | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNPY3 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | called by muse, varscan2
- COL4A2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CORIN | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPAMD8 | c.1037G>A p.C346Y (on ENST00000651564; = p.C299Y on NM_015692.5) | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CSMD1 | c.9652C>A p.P3218T (on ENST00000520002; = p.P3217T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.426); called by muse, mutect2
- CSMD1 | c.5796C>A p.Y1932* (on ENST00000520002; = p.Y1931* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 63/157 reads (40%) | called by muse, mutect2, varscan2
- CTAGE9 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, varscan2
- CYP11B1 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 82/1038 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.078); called by muse, mutect2
- CYP2R1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- DACH1 | c.917del p.P306Rfs*12 | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | called by mutect2, pindel, varscan2
- DDX51 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DHDDS | c.951G>C p.L317F (on ENST00000236342 / NM_001319959.1; = p.L318F on NM_024887.3) | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAH10 | c.7992T>A p.H2664Q (on ENST00000409039; = p.H2603Q on NM_207437.3) | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH3 | c.5392G>A p.A1798T | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK10 | c.3126C>G p.Y1042* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- DPEP1 | c.1000dup p.T334Nfs*11 | Frame Shift Ins (INS) | VAF 33/176 reads (19%) | called by mutect2, varscan2
- DPEP1 | c.1001delinsAA p.T334Kfs*11 | Frame Shift Ins (INS) | VAF 31/209 reads (15%) | called by mutect2*, pindel, varscan2*
- DSG2 | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- EDIL3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.636); called by muse, varscan2
- EEF1D | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- EIF2S2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2
- EIF4E2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ERCC3 | c.2277G>T p.M759I | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EYS | c.6328A>T p.N2110Y | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM209B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 187/508 reads (37%) | called by muse, mutect2, varscan2
- FAM47A | c.744_747del p.P249Gfs*16 | Frame Shift Del (DEL) | VAF 23/168 reads (14%) | called by mutect2, pindel, varscan2
- FAM50B | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- FAP | c.2250C>A p.H750Q | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FASN | c.5992G>C p.G1998R | Missense Mutation (SNP) | VAF 213/549 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.6135G>T p.E2045D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT2 | c.7383C>A p.F2461L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAXC | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FCN1 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- FCRL1 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- FER1L5 | c.2332_2334del p.V778del (on ENST00000623019; = p.V783del on NM_001293083.2) | In Frame Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- FER1L6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.5174C>A p.A1725D | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF13 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 192/271 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGG | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLNC | c.4271G>A p.G1424E | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FMN2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXC2 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRMPD2 | c.2273A>T p.K758M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYB1 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 61/401 reads (15%) | called by muse, mutect2, varscan2
- GAK | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GATA4 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GCLC | c.1401+1G>T p.X467_splice (on ENST00000643939; = p.X465_splice on NM_001498.4) | Splice Site (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- GFRA4 | c.473C>T p.A158V (on ENST00000319242 / NM_145762.3; = p.P132S on NM_022139.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GK3P | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- GMPR | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GOLGA5 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GOLGA6L4 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GPR50 | c.1800C>A p.Y600* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- GYS2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HAP1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HCK | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN1 | c.817A>T p.R273W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HHIPL2 | c.2133G>T p.R711S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK3 | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HNF1B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- HOXC13 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HRNR | c.1672T>A p.Y558N | Missense Mutation (SNP) | VAF 54/636 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2
- HSF2 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFT140 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2
- IGF1R | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-16 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGKV1-17 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGLV3-19 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IGSF3 | c.1629G>A p.M543I (on ENST00000369486 / NM_001007237.3; = p.M563I on NM_001542.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGSF5 | c.140dup p.N47Kfs*29 | Frame Shift Ins (INS) | VAF 15/101 reads (15%) | called by mutect2, pindel
- INSC | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- INTS3 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- ITGB1 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2
- ITSN2 | c.3178G>C p.V1060L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- JMJD1C | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAT6B | c.4303G>T p.E1435* | Nonsense Mutation (SNP) | VAF 33/222 reads (15%) | called by muse, mutect2, varscan2
- KCND1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KCND2 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCNH7 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ2 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1671 | c.5032G>A p.E1678K | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KLHL29 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLRC3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.418); called by muse, mutect2
- LCE1A | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- LCE1D | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 57/315 reads (18%) | PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LCOR | c.379A>T p.K127* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- LMLN | c.404del p.R135Hfs*111 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- LPA | c.5818A>G p.I1940V | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPAR5 | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRBA | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LTBP2 | c.4228C>A p.R1410S | Missense Mutation (SNP) | VAF 161/346 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MAB21L1 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MAFB | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 134/399 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6B | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MAGEB6B | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, varscan2
- MAGEB6B | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- MAP3K6 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD5 | c.1002A>T p.Q334H | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCAT | c.512-2A>T p.X171_splice | Splice Site (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- MEF2C | c.237del p.T80Qfs*9 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | called by mutect2, pindel, varscan2
- MEIS1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 206/345 reads (60%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MOGAT2 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MORC1 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRC2 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- MRM1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MSLNL | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MSMB | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- MTOR | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MTUS2 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC22 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- MUC4 | c.6079A>G p.T2027A | Missense Mutation (SNP) | VAF 105/700 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.224); called by mutect2, varscan2
- MUC5B | c.6518G>A p.S2173N | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MXRA5 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7B | c.642del p.K215Sfs*12 | Frame Shift Del (DEL) | VAF 64/196 reads (33%) | called by mutect2, pindel, varscan2
- MYRF | c.1700C>T p.P567L (on ENST00000278836 / NM_001127392.3; = p.P558L on NM_013279.4) | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- N4BP2L2 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEBL | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2
- NLN | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRAS | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NRN1 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NUP153 | c.4367C>G p.S1456C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP153 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP155 | c.723+2T>G p.X241_splice (on ENST00000231498 / NM_153485.3; = p.X182_splice on NM_004298.4) | Splice Site (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- NXPE3 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H1 | c.338del p.T113Nfs*7 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- OR13F1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OR2AT4 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- OR2C3 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- OR3A2 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- OR4C11 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4K1 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- OR5L2 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 86/161 reads (53%) | called by muse, mutect2, varscan2
- OR6B2 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6K6 | c.140A>T p.H47L (on ENST00000368144; = p.H23L on NM_001005184.1) | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTUD7A | c.1365G>C p.E455D (on ENST00000307050 / NM_001382637.1; = p.E448D on NM_130901.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PALLD | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PARD3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHA12 | c.2308A>T p.M770L | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHGA9 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PDE7B | c.492_494del p.E164del | In Frame Del (DEL) | VAF 24/110 reads (22%) | called by pindel, varscan2
- PDE9A | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PGAP6 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.7042A>G p.K2348E | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKD1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLBD2 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- PLBD2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PLCB1 | c.3440A>T p.E1147V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PLEKHG4B | c.2261G>T p.G754V (on ENST00000283426; = p.G1110V on NM_052909.5) | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEKHG4B | c.2909C>T p.A970V (on ENST00000283426; = p.A1326V on NM_052909.5) | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLG | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLOD3 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 166/428 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR4 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PLRG1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.028); called by muse, mutect2
- PLSCR3 | c.725del p.G242Afs*23 | Frame Shift Del (DEL) | VAF 30/252 reads (12%) | called by mutect2, pindel, varscan2
- PLSCR3 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- POM121L12 | c.45dup p.W16Lfs*130 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | called by mutect2, pindel
- POTEA | c.917A>G p.K306R (on ENST00000519951 / NM_001005365.2; = p.K260R on NM_001002920.1) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POU3F3 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1G | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, mutect2
- PRB1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PRDM5 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); called by muse, mutect2
- PRKCB | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PTCH2 | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- PTTG1 | c.520T>A p.W174R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- QKI | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- QRICH1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); called by muse, mutect2
- RAD51AP2 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- RASGRP4 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASIP1 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RBM15 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RBM15B | c.832del p.R278Vfs*50 | Frame Shift Del (DEL) | VAF 25/200 reads (13%) | called by mutect2, pindel, varscan2
- RDH10 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- REEP5 | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, varscan2
- RFX7 | c.635G>C p.R212P (on ENST00000559447 / NM_001368074.1; = p.R309P on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RNF148 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSRC2 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- RYR3 | c.6381C>A p.A2127= | Splice Region (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- SALL3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SAP130 | c.2988+1G>T p.X996_splice | Splice Site (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- SAXO1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SCAF1 | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SCG2 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SCRT1 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SEL1L3 | c.2670-1G>T p.X890_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SEMA3B | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIPA1L2 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SLC2A12 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC6A18 | c.1555dup p.T519Nfs*129 | Frame Shift Ins (INS) | VAF 14/154 reads (9%) | called by mutect2, pindel
- SLC8A1 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SMG5 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- SMYD5 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOD3 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 170/414 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SRGAP1 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- STAB1 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- STYXL2 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SUCNR1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.194del p.P65Hfs*30 | Frame Shift Del (DEL) | VAF 85/144 reads (59%) | called by mutect2, pindel, varscan2
- SVEP1 | c.5924C>G p.T1975R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SYNE2 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TAF15 | c.376C>T p.Q126* (on ENST00000605844 / NM_139215.3; = p.Q123* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TCP10L | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TESPA1 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 121/199 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAP4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 55/296 reads (19%) | called by muse, mutect2, varscan2
- TFDP3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- THNSL2 | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.4192G>T p.G1398C (on ENST00000272643; = p.G1396C on NM_001316349.2) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD2 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- TLR6 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM121 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TMEM200A | c.1440C>G p.N480K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, varscan2
- TMEM263 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM40 | c.418_424+17del p.X140_splice | Splice Site (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- TOP2B | c.4468A>G p.K1490E (on ENST00000264331 / NM_001330700.2; = p.K1485E on NM_001068.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRHDE | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- TRIM60 | c.275_278del p.K92Rfs*12 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- TRPS1 | c.1127A>T p.E376V (on ENST00000220888 / NM_001330599.2; = p.E389V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TRPS1 | c.1126G>T p.E376* (on ENST00000220888 / NM_001330599.2; = p.E389* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/288 reads (11%) | called by muse, mutect2, varscan2
- TSC2 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
- TTLL13P | c.2318C>G p.S773* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- UBR3 | c.5576A>T p.K1859M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UNC13C | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- UNC45B | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5D | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2
- UNC79 | c.4549C>A p.H1517N (on ENST00000393151 / NM_001346218.2; = p.H1340N on NM_020818.5) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC80 | c.8716A>T p.K2906* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- USP48 | c.1451-3C>G | Splice Region (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- UTP18 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VPS13B | c.3984G>C p.W1328C | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- VPS45 | c.522G>C p.M174I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- VWA5B1 | c.2223C>G p.C741W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WDFY4 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WDR43 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by mutect2, varscan2
- WEE2 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WWC2 | c.535_538del p.K179Efs*6 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel
- XAGE5 | c.115del p.E39Kfs*89 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by pindel, varscan2
- XIRP2 | c.2256T>A p.D752E (on ENST00000628543; = p.D927E on NM_152381.6) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XKR6 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF6 | c.594C>A p.A198= | Splice Region (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- ZAN | c.6200G>T p.G2067V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZBTB21 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- ZFP82 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ZIC5 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 135/236 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 85/137 reads (62%) | called by muse, mutect2, varscan2
- ZNF441 | c.1510A>T p.K504* | Nonsense Mutation (SNP) | VAF 32/50 reads (64%) | called by muse, mutect2, varscan2
- ZNF521 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZNF600 | c.503del p.G168Afs*10 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ZNF623 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ZNF626 | c.102A>T p.L34F | Missense Mutation (SNP) | VAF 126/182 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, varscan2
- ZNF638 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 28/172 reads (16%) | PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZNF638 | c.1995G>T p.K665N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF679 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF699 | c.1928A>C p.*643Sext*2 | Nonstop Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- ZNF804A | c.3503A>T p.Q1168L | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF831 | c.4529G>T p.S1510I | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF853 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNRF3 | c.1096G>A p.V366M (on ENST00000544604 / NM_001206998.2; = p.V266M on NM_032173.3) | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ACSM2A | c.1212C>A p.P404= (on ENST00000219054; = p.P325= on NM_001308169.2) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54584720; called by muse, mutect2, varscan2
- ADAM23 | c.2337C>A p.P779= | Silent (SNP) | VAF 42/305 reads (14%) | catalogued as rs571615571, COSV52217714; called by muse, mutect2, varscan2
- AMER3 | c.1548C>A p.P516= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1319690380; called by muse, mutect2
- ARAP3 | c.213G>T p.L71= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- ASB16 | c.1356C>A p.I452= | Silent (SNP) | VAF 76/134 reads (57%) | called by muse, varscan2
- ASXL3 | c.5649C>T p.S1883= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs775666145; called by muse, mutect2, varscan2
- ATAD3B | c.429C>T p.A143= (on ENST00000308647; = p.A249= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- AWAT2 | c.162C>A p.T54= | Silent (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- AXDND1 | c.825G>T p.V275= | Silent (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- BRD9 | c.1596G>A p.Q532= | Silent (SNP) | VAF 16/280 reads (6%) | called by muse, mutect2
- BRINP1 | c.1878T>A p.P626= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- BUB3 | c.114C>G p.S38= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- C1QL2 | c.447G>A p.A149= | Silent (SNP) | VAF 39/195 reads (20%) | called by muse, mutect2, varscan2
- CABS1 | c.853C>T p.L285= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs201758701; called by muse, mutect2, varscan2
- CACNA1G | c.5283C>T p.G1761= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs775368690; called by muse, mutect2, varscan2
- CCDC168 | c.14673G>A p.R4891= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- CD84 | c.996C>T p.D332= (on ENST00000311224 / NM_001184879.2; = p.D315= on NM_003874.4) | Silent (SNP) | VAF 42/185 reads (23%) | called by muse, mutect2, varscan2
- CDKN2AIPNL | c.138C>A p.R46= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- CEP131 | c.1734G>T p.L578= (on ENST00000269392 / NM_001319228.2; = p.L575= on NM_014984.4) | Silent (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- CEP135 | c.861G>T p.L287= | Silent (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- CFAP46 | c.1251G>A p.L417= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs915842697; called by muse, mutect2, varscan2
- CFAP52 | c.1395C>A p.S465= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2, varscan2
- CHAT | c.1116C>T p.S372= | Silent (SNP) | VAF 45/427 reads (11%) | called by muse, mutect2, varscan2
- CHST3 | c.531G>A p.G177= | Silent (SNP) | VAF 61/501 reads (12%) | called by muse, mutect2, varscan2
- COL11A1 | c.5119C>A p.R1707= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as rs757608461, COSV62179966, COSV62203151; called by muse, mutect2, varscan2
- COL12A1 | c.7311C>G p.S2437= | Silent (SNP) | VAF 27/252 reads (11%) | catalogued as COSV59400696; called by muse, mutect2
- COL24A1 | c.2826T>A p.G942= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- COL9A2 | c.498G>T p.L166= | Silent (SNP) | VAF 84/272 reads (31%) | called by muse, mutect2, varscan2
- CPOX | c.390C>T p.F130= | Silent (SNP) | VAF 120/512 reads (23%) | called by muse, mutect2, varscan2
- CSMD3 | c.9822A>T p.V3274= (on ENST00000297405 / NM_001363185.1; = p.V3105= on NM_052900.3) | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as COSV52209229; called by muse, mutect2, varscan2
- CT47B1 | c.219C>G p.A73= | Silent (SNP) | VAF 299/561 reads (53%) | catalogued as COSV64891143; called by muse, mutect2, varscan2
- CTF1 | c.600G>A p.S200= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs1026759136; called by muse, mutect2, varscan2
- CUX2 | c.2187G>A p.E729= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.306C>A p.I102= | Silent (SNP) | VAF 40/257 reads (16%) | called by muse, mutect2, varscan2
- DDX39A | c.840C>G p.L280= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV54391403; called by muse, mutect2, varscan2
- DIAPH1 | c.2205C>T p.G735= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- DNAI2 | c.912G>T p.V304= | Silent (SNP) | VAF 131/280 reads (47%) | called by muse, mutect2, varscan2
- DOK6 | c.774C>A p.S258= | Silent (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- DYTN | c.1485T>A p.V495= | Silent (SNP) | VAF 61/526 reads (12%) | called by muse, mutect2, varscan2
- ECE1 | c.207G>T p.L69= | Silent (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- ERBB4 | c.318T>A p.R106= | Silent (SNP) | VAF 27/223 reads (12%) | called by muse, mutect2, varscan2
- FAM120C | c.2929C>A p.R977= | Silent (SNP) | VAF 25/158 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.600G>T p.V200= | Silent (SNP) | VAF 92/142 reads (65%) | called by muse, mutect2, varscan2
- FCRL3 | c.1428C>T p.P476= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs1468155648, COSV100943017, COSV63840188; called by muse, mutect2, varscan2
- FECH | c.456C>T p.P152= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- FHL1 | c.420C>T p.S140= | Silent (SNP) | VAF 97/412 reads (24%) | called by muse, mutect2, varscan2
- FLG | c.8379C>T p.S2793= | Silent (SNP) | VAF 193/1739 reads (11%) | catalogued as rs747057114, COSV64240050, COSV64240779; called by muse, mutect2, varscan2
- FLNC | c.7761C>A p.P2587= | Silent (SNP) | VAF 56/140 reads (40%) | called by muse, varscan2
- FN3K | c.324A>C p.A108= | Silent (SNP) | VAF 24/464 reads (5%) | called by muse, mutect2
- GALK1 | c.498C>T p.R166= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs763880577; called by muse, mutect2, varscan2
- GAS2L2 | c.417G>T p.V139= | Silent (SNP) | VAF 99/181 reads (55%) | catalogued as rs781922164; called by muse, mutect2, varscan2
- GAS8 | c.60G>T p.G20= | Silent (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1269C>T p.P423= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as COSV101004208; called by muse, mutect2, varscan2
- GIPR | c.741C>T p.L247= | Silent (SNP) | VAF 40/838 reads (5%) | catalogued as COSV99624748; called by muse, mutect2
- GMPPB | c.1008C>A p.L336= (on ENST00000308388 / NM_021971.4; = p.L363= on NM_013334.3) | Silent (SNP) | VAF 59/130 reads (45%) | called by muse, mutect2, varscan2
- GNAT1 | c.27G>A p.E9= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as COSV104372303; called by muse, mutect2, varscan2
- GRIP1 | c.3114G>A p.G1038= (on ENST00000359742 / NM_001379345.1; = p.G986= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 192/289 reads (66%) | called by muse, mutect2, varscan2
- GRM6 | c.24G>A p.R8= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- GSC | c.186G>A p.V62= | Silent (SNP) | VAF 89/149 reads (60%) | called by muse, mutect2, varscan2
- HELZ2 | c.3861G>C p.L1287= (on ENST00000467148 / NM_001037335.2; = p.L718= on NM_033405.3) | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.528T>G p.T176= (on ENST00000394468 / NM_001039372.4; = p.T164= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/268 reads (38%) | called by muse, mutect2, varscan2
- HMCN1 | c.11865T>A p.L3955= | Silent (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- HPS5 | c.690G>T p.G230= (on ENST00000349215 / NM_181507.2; = p.G116= on NM_007216.4) | Silent (SNP) | VAF 79/134 reads (59%) | catalogued as COSV62540412; called by muse, mutect2, varscan2
- IGF2BP1 | c.105C>G p.V35= | Silent (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- IGKV3-15 | c.204C>A p.I68= | Silent (SNP) | VAF 176/860 reads (20%) | catalogued as rs755211568; called by muse, mutect2, varscan2
- INSC | c.762C>A p.T254= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV65412910; called by muse, mutect2
- IQSEC2 | c.756A>T p.P252= (on ENST00000642864 / NM_001111125.3; = p.P47= on NM_015075.2) | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- IRX1 | c.1392G>A p.L464= | Silent (SNP) | VAF 42/508 reads (8%) | called by muse, mutect2
- ITPKB | c.2796C>G p.L932= | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- KDM4D | c.516A>T p.I172= | Silent (SNP) | VAF 140/187 reads (75%) | called by muse, mutect2, varscan2
- KIAA1217 | c.399G>T p.L133= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2
- KIF16B | c.489G>T p.R163= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- LAMA4 | c.3888G>A p.K1296= (on ENST00000230538 / NM_001105206.3; = p.K1289= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/251 reads (6%) | called by muse, mutect2
- LBP | c.954C>G p.T318= | Silent (SNP) | VAF 86/255 reads (34%) | called by muse, mutect2, varscan2
- LEUTX | c.258T>G p.R86= | Silent (SNP) | VAF 96/147 reads (65%) | called by muse, mutect2, varscan2
- LPA | c.5598C>G p.S1866= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as COSV100305988; called by muse, mutect2, varscan2
- LRRIQ3 | c.1431G>A p.E477= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- LRRN4 | c.1782G>T p.T594= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- MADCAM1 | c.996G>T p.L332= | Silent (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1845C>A p.A615= | Silent (SNP) | VAF 81/116 reads (70%) | catalogued as COSV100026254; called by muse, mutect2, varscan2
- MAP6D1 | c.105C>T p.D35= | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as rs1266038451; called by muse, mutect2, varscan2
- MDN1 | c.6210G>T p.V2070= | Silent (SNP) | VAF 140/512 reads (27%) | called by muse, mutect2, varscan2
- MEAK7 | c.804G>T p.L268= | Silent (SNP) | VAF 71/192 reads (37%) | catalogued as COSV59145253; called by muse, mutect2, varscan2
- MEGF11 | c.285C>T p.S95= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as rs878944232, COSV99987805; called by muse, mutect2, varscan2
- MKRN3 | c.1275C>A p.G425= | Silent (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- MRPS21 | c.165A>G p.E55= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- MRTFA | c.1080C>T p.A360= | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as rs1392573674, COSV62933382; called by muse, varscan2
- MSR1 | c.636C>A p.I212= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.6579C>A p.S2193= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- MUC22 | c.300C>T p.D100= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- MUCL3 | c.900C>A p.S300= | Silent (SNP) | VAF 116/372 reads (31%) | called by muse, mutect2, varscan2
- MYH13 | c.4104C>T p.A1368= | Silent (SNP) | VAF 49/442 reads (11%) | catalogued as rs377365193; called by muse, mutect2, varscan2
- MYO18B | c.6810G>T p.L2270= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- MYOM2 | c.1086C>A p.G362= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV50718277; called by muse, mutect2, varscan2
- NBEA | c.4857T>C p.H1619= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- NHLRC1 | c.468A>G p.S156= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as CD033859, COSV100513588; called by muse, mutect2, varscan2
- NMBR | c.1060C>T p.L354= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- NTF4 | c.366C>A p.G122= | Silent (SNP) | VAF 89/311 reads (29%) | called by muse, mutect2, varscan2
- NUTM1 | c.1308G>T p.L436= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs749670673; called by muse, mutect2, varscan2
- OAS2 | c.1902G>T p.V634= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- OR10K1 | c.904C>A p.R302= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV56870768, COSV99193382; called by muse, mutect2, varscan2
- OR10K2 | c.207T>A p.S69= | Silent (SNP) | VAF 89/286 reads (31%) | called by muse, mutect2, varscan2
- OR10X1 | c.180C>T p.I60= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV100936618; called by muse, mutect2, varscan2
- OR2T27 | c.213C>A p.I71= | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- OR4P4 | c.369C>T p.A123= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1274808152; called by muse, mutect2, varscan2
- OR7E24 | c.927C>T p.S309= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- OR9G4 | c.861T>C p.P287= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- PARK7 | c.303G>A p.L101= | Silent (SNP) | VAF 46/249 reads (18%) | called by muse, mutect2, varscan2
- PCDH10 | c.1800C>T p.L600= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV99993195; called by muse, mutect2, varscan2
- PCDHA9 | c.474C>G p.S158= | Silent (SNP) | VAF 107/308 reads (35%) | catalogued as rs781916641, COSV65325536; called by muse, mutect2, varscan2
- PDYN | c.366G>A p.L122= | Silent (SNP) | VAF 66/537 reads (12%) | called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 19/229 reads (8%) | catalogued as COSV56854914; called by muse, mutect2
- PGM5 | c.1518C>A p.I506= | Silent (SNP) | VAF 50/86 reads (58%) | called by muse, mutect2, varscan2
- PIGG | c.2799G>T p.T933= (on ENST00000453061 / NM_001127178.3; = p.T925= on NM_017733.4) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99573659; called by muse, mutect2, varscan2
- PLEKHG2 | c.357G>A p.R119= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- PREX1 | c.3456C>A p.A1152= | Silent (SNP) | VAF 185/401 reads (46%) | called by muse, mutect2, varscan2
- PRR23B | c.738G>T p.A246= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV61493405; called by muse, mutect2, varscan2
- PTCH2 | c.3135C>A p.G1045= | Silent (SNP) | VAF 84/299 reads (28%) | called by muse, mutect2, varscan2
- PTPRN | c.96C>T p.C32= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- RANBP3 | c.618A>T p.A206= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- RBFOX1 | c.159A>T p.T53= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- REPS1 | c.525A>G p.P175= | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- RGL4 | c.240C>T p.P80= | Silent (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- RGPD3 | c.60G>T p.P20= | Silent (SNP) | VAF 36/382 reads (9%) | catalogued as rs778699719; called by muse, mutect2
- RHBDF2 | c.2013C>T p.L671= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs777681843; called by muse, mutect2
- RNF150 | c.744G>T p.L248= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- RREB1 | c.1548G>T p.R516= | Silent (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- RTL9 | c.2637A>T p.T879= | Silent (SNP) | VAF 83/159 reads (52%) | called by muse, mutect2, varscan2
- RUNDC3A | c.504C>A p.T168= | Silent (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- RXFP3 | c.610C>A p.R204= | Silent (SNP) | VAF 125/289 reads (43%) | catalogued as rs754795557, COSV57506270; called by muse, mutect2, varscan2
- SAMD9L | c.741A>T p.G247= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- SCN11A | c.3537G>T p.L1179= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- SCN2A | c.1830T>C p.S610= | Silent (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- SERPINA4 | c.1038T>C p.A346= | Silent (SNP) | VAF 74/199 reads (37%) | called by muse, mutect2, varscan2
- SETD1A | c.4614C>T p.S1538= | Silent (SNP) | VAF 72/173 reads (42%) | catalogued as rs756766457; called by muse, mutect2, varscan2
- SGSM1 | c.2361G>A p.L787= (on ENST00000400359 / NM_001039948.4; = p.L726= on NM_133454.3) | Silent (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4293C>T p.H1431= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs374770438; called by muse, mutect2, varscan2
- SLITRK4 | c.1818C>T p.P606= | Silent (SNP) | VAF 86/135 reads (64%) | catalogued as COSV62026634; called by muse, mutect2, varscan2
- SLITRK5 | c.2523G>A p.R841= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- SMAP1 | c.840G>A p.G280= (on ENST00000370455 / NM_001044305.3; = p.G253= on NM_021940.5) | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- SMIM23 | c.84C>T p.S28= | Silent (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- SOX1 | c.192G>T p.G64= | Silent (SNP) | VAF 218/384 reads (57%) | catalogued as COSV58378315; called by muse, mutect2, varscan2
- SPTA1 | c.6081C>T p.H2027= | Silent (SNP) | VAF 81/255 reads (32%) | catalogued as COSV63751647; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.294G>T p.L98= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100603003; called by muse, mutect2
- SVIL | c.3096G>A p.R1032= (on ENST00000355867 / NM_021738.3; = p.R606= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV63443589; called by muse, mutect2, varscan2
- TAF1 | c.4458G>T p.A1486= (on ENST00000373790 / NM_138923.4; = p.A1507= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV52125753; called by muse, mutect2, varscan2
- TAF6 | c.609G>C p.G203= | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- TEKT4 | c.216G>T p.L72= | Silent (SNP) | VAF 91/141 reads (65%) | called by muse, mutect2, varscan2
- TMEM132C | c.1605G>C p.T535= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as COSV59433699; called by muse, mutect2, varscan2
- TOP1MT | c.24G>T p.R8= | Silent (SNP) | VAF 109/594 reads (18%) | called by muse, mutect2, varscan2
- TPSD1 | c.393G>C p.L131= | Silent (SNP) | VAF 48/271 reads (18%) | catalogued as COSV99273708; called by muse, mutect2, varscan2
- TRIM27 | c.867G>A p.E289= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs757070636; called by muse, mutect2, varscan2
- TTN | c.55689G>A p.V18563= (on ENST00000591111; = p.V11139= on NM_003319.4) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs897086744; called by muse, mutect2, varscan2
- UNC45B | c.2604C>T p.G868= | Silent (SNP) | VAF 45/311 reads (14%) | called by muse, mutect2, varscan2
- USP29 | c.1983G>T p.V661= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as COSV99518309; called by muse, mutect2, varscan2
- VRTN | c.1074C>A p.G358= | Silent (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- WDFY4 | c.6537G>A p.K2179= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99630076; called by muse, mutect2, varscan2
- WDR24 | c.1650G>T p.A550= (on ENST00000248142; = p.A420= on NM_032259.4) | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs772843694, COSV50196971; called by muse, mutect2, varscan2
- WNT3A | c.769C>A p.R257= | Silent (SNP) | VAF 60/186 reads (32%) | called by muse, mutect2, varscan2
- WWC3 | c.2242C>A p.R748= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- XDH | c.342G>A p.G114= | Silent (SNP) | VAF 196/353 reads (56%) | catalogued as rs377004053; called by muse, mutect2, varscan2
- XIRP2 | c.7359A>G p.Q2453= (on ENST00000628543; = p.Q2628= on NM_152381.6) | Silent (SNP) | VAF 29/224 reads (13%) | called by muse, mutect2, varscan2
- XKR7 | c.1158C>A p.L386= | Silent (SNP) | VAF 53/162 reads (33%) | called by muse, mutect2, varscan2
- YBX1 | c.765T>C p.P255= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as rs978665936; called by muse, mutect2
- ZCRB1 | c.417A>G p.K139= | Silent (SNP) | VAF 47/82 reads (57%) | called by muse, mutect2, varscan2
- ZFHX3 | c.7998G>T p.P2666= | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- ZNF208 | c.2760A>G p.E920= | Silent (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- ZNF469 | c.4941C>G p.A1647= (on ENST00000437464; = p.A1675= on NM_001367624.2) | Silent (SNP) | VAF 101/262 reads (39%) | called by muse, mutect2, varscan2
- ZNF516 | c.258G>T p.T86= | Silent (SNP) | VAF 93/226 reads (41%) | called by muse, mutect2, varscan2
- ZNF749 | c.912G>C p.G304= | Silent (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- A4GALT | c.*148A>T | 3'UTR (SNP) | VAF 43/494 reads (9%) | called by muse, mutect2
- AARS1 | c.817-21C>A | Intron (SNP) | VAF 45/406 reads (11%) | called by muse, mutect2, varscan2
- ABCC13 | n.3876G>C | RNA (SNP) | VAF 22/92 reads (24%) | catalogued as rs1415938661; called by muse, mutect2, varscan2
- AC011525.1 | n.850C>A | RNA (SNP) | VAF 64/116 reads (55%) | called by muse, mutect2, varscan2
- AC068633.1 | n.15T>C | RNA (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- AC099548.2 | n.1352A>T | RNA (SNP) | VAF 32/153 reads (21%) | called by mutect2, varscan2
- AC116351.1 | n.1319C>A | RNA (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- AGAP12P | n.1916C>A | RNA (SNP) | VAF 202/1086 reads (19%) | called by mutect2, varscan2
- AGAP12P | n.1915C>A | RNA (SNP) | VAF 215/1157 reads (19%) | called by muse, mutect2, varscan2
- AKAP9 | c.5698-2968G>A | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- AL035696.1 | n.307C>A | RNA (SNP) | VAF 96/199 reads (48%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.395-79G>T | Intron (SNP) | VAF 41/301 reads (14%) | catalogued as rs1039305418; called by muse, mutect2, varscan2
- AMACR | c.-23T>A | 5'UTR (SNP) | VAF 110/255 reads (43%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57015A>C | Intron (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- ARMC6 | c.29+3343G>C | Intron (SNP) | VAF 126/167 reads (75%) | called by muse, mutect2, varscan2
- C4A | chr6:32005725 C>G | 3'Flank (SNP) | VAF 108/484 reads (22%) | called by muse, varscan2
- CD320 | c.-8G>A | 5'UTR (SNP) | VAF 156/291 reads (54%) | catalogued as rs1482476829; called by muse, mutect2, varscan2
- CGREF1 | c.-11-66A>T | Intron (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- CLEC12B | c.680+9C>A | Intron (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.179G>C | RNA (SNP) | VAF 14/86 reads (16%) | called by mutect2, varscan2
- CRISP3 | c.-10C>T | 5'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- DCHS2 | n.3469A>G | RNA (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- DCHS2 | n.2420G>A | RNA (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- DIO3 | chr14:101557544 C>A | 5'Flank (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- DMPK | c.*23C>T | 3'UTR (SNP) | VAF 34/607 reads (6%) | called by muse, mutect2
- DPP8 | c.307+236A>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- EI24P4 | n.873C>G | RNA (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- FCGR2B | c.761-40C>A | Intron (SNP) | VAF 83/154 reads (54%) | catalogued as rs758059520; called by muse, mutect2, varscan2
- FOXP2 | c.*1838G>A | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- GK5 | c.411+24G>T | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- GPHN | c.-46C>T | 5'UTR (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- GRAMD2A | c.134+328G>A | Intron (SNP) | VAF 6/122 reads (5%) | catalogued as rs1384107238; called by muse, mutect2
- HCN1 | c.*19G>A | 3'UTR (SNP) | VAF 30/206 reads (15%) | catalogued as rs1160088971; called by muse, mutect2, varscan2
- HGF | c.482+38C>G | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2
- KCNQ2 | c.1763+107C>A | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- LAIR2 | c.-67G>T | 5'UTR (SNP) | VAF 58/103 reads (56%) | catalogued as rs1333369643; called by muse, mutect2
- LIMS2 | c.360-1022G>T | Intron (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+2692A>T | Intron (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+986C>A | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- MIR9-1 | chr1:156420266 G>T | 3'Flank (SNP) | VAF 150/423 reads (35%) | called by muse, mutect2, varscan2
- MYADML | n.990del | RNA (DEL) | VAF 113/261 reads (43%) | called by mutect2, pindel, varscan2
- NALCN | c.2193-5283C>A | Intron (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- NDRG2 | c.556-15G>T | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.471G>C | RNA (SNP) | VAF 58/488 reads (12%) | catalogued as rs758557798; called by muse, mutect2, varscan2
- OAS3 | c.460+33G>T | Intron (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- ORC6 | c.*199G>T | 3'UTR (SNP) | VAF 78/281 reads (28%) | catalogued as rs773435958; called by muse, mutect2, varscan2
- PCBP3 | c.675+48A>C | Intron (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- PCBP3 | c.675+49C>T | Intron (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- PCYT1B | c.*169C>G | 3'UTR (SNP) | VAF 26/110 reads (24%) | catalogued as COSV63264648; called by muse, mutect2, varscan2
- PDE5A | c.152+1321G>C | Intron (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- PFAS | c.3707-35C>A | Intron (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- PIP | c.*1T>A | 3'UTR (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99344279; called by muse, mutect2
- PLP1 | c.5-4278C>T | Intron (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.-160_-159del | 5'UTR (DEL) | VAF 26/172 reads (15%) | called by pindel, varscan2
- POTEG | c.811-1201G>C | Intron (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2, varscan2
- PRCC | c.1324-13T>C | Intron (SNP) | VAF 55/148 reads (37%) | called by muse, mutect2, varscan2
- PSMC1 | c.-24G>C | 5'UTR (SNP) | VAF 48/228 reads (21%) | called by muse, mutect2, varscan2
34 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 34 other) are not listed here.
